Gene-level copy-number profile of tumor specimen TCGA-IG-A5B8-01A from TCGA case TCGA-IG-A5B8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 72.8 years (26,574 days).
Specimen TCGA-IG-A5B8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.63635c91-4b65-4e7a-9468-51f15ceec4e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A5B8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98dbe959-58c1-4ab6-8e80-8b691348b669

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 12,483; copy number 2: 35,117; copy number 3: 10,343; copy number 4: 1,863; copy number 5: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A5B8-01A-11D-A28A-01): tumor purity 0.36, ploidy 3.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:31,975,167–32,031,639, 2 genes: Metazoa_SRP, FRY-AS1.
- chr20:54,859,688–55,781,231, 7 genes: RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:54,153,446–54,651,169, 5 genes, copy number 5: CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 10,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
